Somatic mutation profile of tumor specimen C3N-02264-01 (aliquot CPT0188850006) from CPTAC case C3N-02264, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 68.5 years (25,037 days).
Specimen C3N-02264-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5154466d-a16d-49dc-a7ef-6089e7620688.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02264-31 (Blood Derived Normal), aliquot CPT0188890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab9555bd-bccd-4482-bf65-dc2f965b3057

The open-access MAF lists 119 somatic variants for this specimen: 83 protein-altering or splice-affecting, 21 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 21, Nonsense Mutation 7, Intron 7, Frame Shift Del 6, 5'UTR 5, 3'Flank 2, Splice Region 1, Splice Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 44/409 reads (11%) | catalogued as rs1553645164, CM123455, COSV56230370; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.922C>A p.H308N | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100036726; called by muse, mutect2
- ALG12 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 53/474 reads (11%) | PolyPhen possibly damaging (0.472); catalogued as rs1290037470; called by muse, mutect2, varscan2
- APOB | c.10586C>G p.S3529* | Nonsense Mutation (SNP) | VAF 20/306 reads (7%) | catalogued as COSV51956291; called by muse, mutect2
- CCDC8 | c.768T>A p.C256* | Nonsense Mutation (SNP) | VAF 39/324 reads (12%) | catalogued as COSV56772271; called by muse, mutect2, varscan2
- CD93 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs771340823; called by muse, mutect2, varscan2
- DCHS1 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100201863; called by muse, mutect2, varscan2
- KLK11 | c.242C>T p.A81V (on ENST00000594768 / NM_144947.3; = p.A49V on NM_006853.3) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs201147335, COSV99141918; called by muse, mutect2, varscan2
- KRT12 | c.997A>T p.T333S | Missense Mutation (SNP) | VAF 72/798 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV52431024; called by muse, mutect2
- MROH9 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs750550050, COSV63010911; called by muse, mutect2
- MTOR | c.7247C>A p.A2416D | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63868538, COSV63873144; called by muse, mutect2
- POLE | c.6379C>T p.R2127* | Nonsense Mutation (SNP) | VAF 51/422 reads (12%) | catalogued as rs1057517583, COSV57681995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRAMEF19 | c.1090T>G p.S364A | Missense Mutation (SNP) | VAF 82/1082 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.495); catalogued as rs747475616; called by muse, mutect2
- PRODH2 | c.418C>T p.R140W (on ENST00000301175; = p.R64W on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1160823162; called by muse, mutect2
- RIMS3 | c.650C>G p.T217S | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs1460399816; called by muse, mutect2
- SDK1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 50/530 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs539684931, COSV67377081; called by muse, mutect2
- SLC12A8 | c.2133G>A p.M711I | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.02); catalogued as COSV100102242; called by muse, mutect2
- SLC28A3 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66152578; called by muse, mutect2
- VHL | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as CD031547, CM071137, CM961422, COSV56545382, COSV56546949, COSV56570017, COSV56573703; called by muse, mutect2
- ZNF384 | c.1670A>T p.H557L (on ENST00000361959; = p.H496L on NM_133476.5) | Missense Mutation (SNP) | VAF 52/540 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV58556792; called by muse, mutect2
- ABCC10 | c.353C>A p.A118D (on ENST00000372530 / NM_001198934.2; = p.A75D on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ABCC2 | c.1133T>G p.L378R | Missense Mutation (SNP) | VAF 59/641 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ABCC2 | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ACVR1B | c.806_811+8del p.X269_splice | Splice Site (DEL) | VAF 12/110 reads (11%) | called by mutect2, pindel
- AMDHD2 | c.350T>A p.V117D | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.281); called by muse, mutect2
- ANXA11 | c.41del p.P14Hfs*137 | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by mutect2, pindel, varscan2
- ASTN1 | c.2227C>G p.Q743E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, varscan2
- CAPG | c.297G>C p.Q99H | Missense Mutation (SNP) | VAF 52/443 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLIP1 | c.1861G>A p.A621T (on ENST00000620786 / NM_001247997.1; = p.A610T on NM_002956.2) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- DHRS7 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- DICER1 | c.3344C>T p.S1115L | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLEU7 | c.651T>G p.N217K | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DSG1 | c.1778C>A p.A593E | Missense Mutation (SNP) | VAF 86/747 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- EHD1 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- ELAVL4 | c.550A>T p.I184F | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- EPHB6 | c.2119G>C p.A707P | Missense Mutation (SNP) | VAF 74/535 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ESPL1 | c.2261G>T p.W754L | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM102A | c.512T>C p.L171P (on ENST00000373095 / NM_001035254.3; = p.L29P on NM_203305.2) | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBN2 | c.8221A>T p.K2741* | Nonsense Mutation (SNP) | VAF 34/426 reads (8%) | called by muse, mutect2
- FGF14 | c.241T>G p.Y81D | Missense Mutation (SNP) | VAF 54/471 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GAPT | c.135G>T p.R45S | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- GEMIN5 | c.409T>C p.Y137H | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GK5 | c.647A>C p.N216T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GPR176 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 37/322 reads (11%) | called by muse, mutect2, varscan2
- HAPLN2 | c.663del p.I223Sfs*34 | Frame Shift Del (DEL) | VAF 47/339 reads (14%) | called by mutect2, pindel, varscan2
- HOXB2 | c.483A>C p.E161D | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- HTR1E | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- IARS1 | c.1630A>T p.N544Y | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2
- ITGA10 | c.3439-4A>G | Splice Region (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- JUND | c.827_831del p.L276Qfs*146 | Frame Shift Del (DEL) | VAF 102/1131 reads (9%) | called by mutect2, pindel
- LATS2 | c.1291A>C p.T431P | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by mutect2, varscan2
- LRIG3 | c.2187C>A p.N729K | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- LTB4R | c.164del p.L55Rfs*4 | Frame Shift Del (DEL) | VAF 25/239 reads (10%) | called by mutect2, varscan2
- MICAL1 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- MICAL3 | c.3229G>A p.D1077N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2
- MICALL2 | c.851C>A p.P284Q | Missense Mutation (SNP) | VAF 62/619 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.05); called by muse, mutect2
- MTMR7 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); called by muse, mutect2
- MUC13 | c.1474T>A p.S492T | Missense Mutation (SNP) | VAF 56/505 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- NRXN2 | c.1666A>G p.M556V | Missense Mutation (SNP) | VAF 70/678 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- NUGGC | c.1444C>A p.P482T | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PGM1 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2R1 | c.2829G>A p.W943* | Nonsense Mutation (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- PNLIPRP2 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 54/620 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.106); called by muse, mutect2
- PRR14L | c.1069A>G p.I357V | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2
- QDPR | c.122A>T p.D41V | Missense Mutation (SNP) | VAF 52/540 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- RENBP | c.998T>A p.F333Y | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- REV3L | c.3186del p.Q1062Hfs*40 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel, varscan2
- RIPK4 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 56/558 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2
- SH3PXD2A | c.2621A>G p.E874G (on ENST00000369774 / NM_001365079.1; = p.E846G on NM_014631.2) | Missense Mutation (SNP) | VAF 29/370 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- SLC17A1 | c.1337del p.F446Sfs*4 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- SLC25A12 | c.898T>A p.L300I | Missense Mutation (SNP) | VAF 38/465 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- SLC7A6 | c.1173C>G p.N391K | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TANC1 | c.4868A>G p.K1623R | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- TP53BP2 | c.1670C>G p.P557R (on ENST00000343537 / NM_001031685.3; = p.P428R on NM_005426.2) | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TRPS1 | c.3155G>C p.S1052T (on ENST00000220888 / NM_001330599.2; = p.S1065T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/540 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.437); called by muse, mutect2
- UBD | c.329G>C p.S110T | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- UTP4 | c.2045A>C p.K682T | Missense Mutation (SNP) | VAF 51/451 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WDR20 | c.1300A>G p.S434G | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- WDR26 | c.752C>T p.S251L (on ENST00000414423 / NM_001379403.1; = p.S151L on NM_025160.7) | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- XPNPEP2 | c.1186_1212del p.S396_F404del | In Frame Del (DEL) | VAF 23/195 reads (12%) | called by mutect2, pindel
- YME1L1 | c.1162C>T p.L388F (on ENST00000326799 / NM_139312.3; = p.L331F on NM_014263.4) | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF225 | c.1649A>T p.N550I | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF281 | c.908T>A p.L303Q | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY10 | c.2697G>T p.L899= | Silent (SNP) | VAF 51/479 reads (11%) | called by muse, mutect2, varscan2
- AHNAK | c.5343C>G p.V1781= | Silent (SNP) | VAF 43/537 reads (8%) | catalogued as rs372710026, COSV57212459; called by muse, mutect2
- CD248 | c.513G>C p.A171= | Silent (SNP) | VAF 25/215 reads (12%) | called by muse, mutect2, varscan2
- ECT2 | c.1755A>C p.G585= (on ENST00000392692 / NM_001349098.2; = p.G554= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- FOXP4 | c.1557C>T p.L519= (on ENST00000307972 / NM_001012426.1; = p.L506= on NM_138457.3) | Silent (SNP) | VAF 38/290 reads (13%) | catalogued as COSV100332627; called by muse, mutect2, varscan2
- GRIN1 | c.291C>G p.T97= | Silent (SNP) | VAF 43/399 reads (11%) | called by muse, mutect2, varscan2
- HRNR | c.2370C>T p.S790= | Silent (SNP) | VAF 60/424 reads (14%) | catalogued as rs374698370; called by muse, mutect2, varscan2
- IP6K3 | c.387C>G p.A129= | Silent (SNP) | VAF 44/385 reads (11%) | called by muse, mutect2, varscan2
- MANEA | c.888T>C p.D296= | Silent (SNP) | VAF 25/259 reads (10%) | called by muse, mutect2
- MCHR1 | c.225G>T p.S75= | Silent (SNP) | VAF 44/454 reads (10%) | called by muse, mutect2
- MCHR1 | c.226C>T p.L76= | Silent (SNP) | VAF 44/446 reads (10%) | called by muse, mutect2
- MORC4 | c.816T>C p.C272= | Silent (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2
- OR11H4 | c.633T>G p.T211= | Silent (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- OTOA | c.1983G>A p.G661= (on ENST00000286149; = p.G647= on NM_144672.4) | Silent (SNP) | VAF 74/722 reads (10%) | called by muse, mutect2, varscan2
- PDGFRA | c.2985C>T p.N995= | Silent (SNP) | VAF 31/357 reads (9%) | catalogued as rs138801854; ClinVar: likely benign; called by muse, mutect2
- RENBP | c.999C>T p.F333= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as rs782138348; called by muse, mutect2, varscan2
- SEC31B | c.591T>C p.D197= | Silent (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- SF3B3 | c.180T>C p.G60= | Silent (SNP) | VAF 27/316 reads (9%) | catalogued as COSV56784947; called by muse, mutect2
- SLC35D3 | c.600G>A p.L200= | Silent (SNP) | VAF 33/355 reads (9%) | called by muse, mutect2
- SLC6A20 | c.1134C>T p.Y378= | Silent (SNP) | VAF 51/270 reads (19%) | called by muse, mutect2, varscan2
- TUBB2A | c.375G>A p.E125= | Silent (SNP) | VAF 27/456 reads (6%) | called by muse, mutect2
- AREL1 | c.-20G>A | 5'UTR (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- ATL2 | c.1633-444C>G | Intron (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2, varscan2
- FAM178B | c.-49C>T | 5'UTR (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- FNIP2 | c.655+234G>T | Intron (SNP) | VAF 10/94 reads (11%) | called by muse, varscan2
- KCNB1 | c.-187C>T | 5'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- MAG | c.1716+269A>T | Intron (SNP) | VAF 40/404 reads (10%) | called by muse, mutect2
- MEGF11 | c.2711-3631G>A | Intron (SNP) | VAF 24/296 reads (8%) | catalogued as rs988373445; called by muse, mutect2
- MYCBP | c.-22C>T | 5'UTR (SNP) | VAF 20/170 reads (12%) | called by muse, mutect2, varscan2
- NQO1 | chr16:69707138 T>A | 3'Flank (SNP) | VAF 14/263 reads (5%) | catalogued as rs1402219391; called by muse, mutect2
- PLEKHG3 | chr14:64749238 G>C | 3'Flank (SNP) | VAF 44/313 reads (14%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.754+34T>A | Intron (SNP) | VAF 13/145 reads (9%) | called by muse, mutect2
- SPRING1 | c.*7C>T | 3'UTR (SNP) | VAF 10/110 reads (9%) | catalogued as rs755438323; called by muse, mutect2
- WASHC5 | c.-22A>G | 5'UTR (SNP) | VAF 34/363 reads (9%) | called by muse, mutect2
- ZBTB11 | c.546+11C>G | Intron (SNP) | VAF 26/244 reads (11%) | catalogued as rs374771199; called by muse, mutect2, varscan2
- ZNF160 | c.16-552A>G | Intron (SNP) | VAF 10/92 reads (11%) | called by muse, varscan2
